Somatic mutation profile of tumor specimen TCGA-AA-3666-01A (aliquot TCGA-AA-3666-01A-02W-0900-09) from TCGA case TCGA-AA-3666, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-AA-3666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bab0367-3649-4f61-8609-c63b5fa025f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3666-10A (Blood Derived Normal), aliquot TCGA-AA-3666-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b59ea737-b747-4912-9c78-6a88d7fb8f6c

The open-access MAF lists 191 somatic variants for this specimen: 150 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 39, Nonsense Mutation 9, Frame Shift Del 3, Splice Site 3, RNA 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 196/384 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- SLC45A2 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 53/290 reads (18%) | catalogued as rs794727511, COSV56874814; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.326T>G p.F109C | Missense Mutation (SNP) | VAF 132/164 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796722, COSV52725602, COSV52838438; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11577A>C p.Q3859H | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV71293139; called by muse, mutect2, varscan2
- ADCY8 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 199/363 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs75890340, COSV53923023; called by muse, mutect2, varscan2
- AGBL5 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 8/208 reads (4%) | catalogued as COSV100548976; called by muse, mutect2
- AGO1 | c.1481A>G p.Q494R | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100940787; called by mutect2, varscan2
- AKAP6 | c.5563C>T p.R1855C | Missense Mutation (SNP) | VAF 164/216 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs768396047, COSV55229119; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 90/99 reads (91%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- ANKRD30A | c.1394-1G>T p.X465_splice (on ENST00000611781; = p.X409_splice on NM_052997.2) | Splice Site (SNP) | VAF 43/231 reads (19%) | catalogued as rs1229815239, COSV100653154, COSV64615813; called by muse, mutect2, varscan2
- APOBEC3D | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV53328247; called by muse, mutect2, varscan2
- AR | c.2024T>C p.L675P | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104424813, COSV65962928; called by muse, mutect2, varscan2
- ARSD | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs139907025, COSV54202586; called by muse, mutect2, varscan2
- ASTN1 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375497555; called by muse, mutect2, varscan2
- BEND2 | c.2061C>A p.S687R | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV66216949; called by muse, mutect2, varscan2
- BMP5 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748959947, COSV63705821; called by muse, mutect2
- BRPF1 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1305258410, COSV57407267; called by muse, mutect2, varscan2
- C8B | c.207T>G p.S69R | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV64777384; called by muse, mutect2, varscan2
- CADM1 | c.1178T>C p.I393T | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59020625; called by muse, mutect2, varscan2
- CAPN11 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV101291864; called by muse, mutect2
- CDIN1 | c.319T>G p.F107V (on ENST00000437989; = p.F9V on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.672); catalogued as rs763900403, COSV57713939; called by muse, mutect2, varscan2
- CEP89 | c.307C>G p.P103A | Missense Mutation (SNP) | VAF 262/395 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV59867104; called by muse, mutect2, varscan2
- CFAP57 | c.1256A>C p.E419A | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV100763997; called by muse, mutect2
- CFH | c.2088A>C p.E696D | Missense Mutation (SNP) | VAF 122/588 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV66412147; called by muse, mutect2, varscan2
- CLCN5 | c.1784T>G p.L595W | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV56586461; called by muse, mutect2, varscan2
- CLP1 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57055646; called by muse, mutect2, varscan2
- COL18A1 | c.1552G>T p.E518* (on ENST00000359759 / NM_130444.3; = p.E283* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV62706259; called by muse, mutect2, varscan2
- COL4A6 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as rs745484454, COSV57867389; called by muse, mutect2
- CPO | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV55941278; called by muse, mutect2, varscan2
- CRYBG3 | c.7904A>C p.K2635T | Missense Mutation (SNP) | VAF 41/411 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV51715289; called by muse, mutect2
- CSMD1 | c.5644C>A p.L1882M (on ENST00000520002; = p.L1881M on NM_033225.6) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59370955; called by muse, mutect2, varscan2
- CSNK1A1L | c.8A>C p.N3T | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV65790068; called by muse, mutect2
- DAO | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as COSV57321867; called by muse, mutect2, varscan2
- DCLK1 | c.1790T>C p.L597P | Missense Mutation (SNP) | VAF 62/666 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55205225; called by muse, mutect2
- DLG1 | c.1619C>A p.T540K | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as CM1514809, COSV58389472; called by muse, mutect2, varscan2
- DMXL1 | c.2107A>G p.S703G | Missense Mutation (SNP) | VAF 156/252 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60719304; called by muse, mutect2, varscan2
- EMB | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs1374322156, COSV57484035; called by muse, mutect2, varscan2
- EPHA5 | c.1915A>T p.N639Y | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV56667768; called by muse, mutect2, varscan2
- EPYC | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99664559; called by muse, mutect2
- ERCC6 | c.2354T>A p.V785D | Missense Mutation (SNP) | VAF 86/427 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63393627; called by muse, mutect2, varscan2
- EXT1 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV65483886; called by muse, mutect2, varscan2
- FAM126A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/455 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV101299999; called by muse, mutect2
- FBH1 | c.1321C>G p.L441V (on ENST00000362091 / NM_178150.3; = p.L492V on NM_032807.4) | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV62984168; called by muse, mutect2
- FBXO38 | c.3208C>G p.R1070G (on ENST00000340253 / NM_205836.3; = p.R995G on NM_030793.5) | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57030854; called by muse, mutect2, varscan2
- FGA | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771023837, COSV57399872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXD4L4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1352810874; called by muse, mutect2, varscan2
- GABRA1 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 34/138 reads (25%) | catalogued as COSV50115894; called by muse, mutect2, varscan2
- GJD4 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.258); catalogued as COSV58703257; called by muse, mutect2, varscan2
- GML | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV55278268, COSV55278556; called by muse, mutect2, varscan2
- GNAQ | c.542G>C p.R181T | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54122917; called by muse, mutect2, varscan2
- GRIA2 | c.440A>C p.K147T | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV99643610, COSV99645191; called by muse, mutect2
- GSDMC | c.1347A>T p.K449N | Missense Mutation (SNP) | VAF 127/218 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV52698449; called by muse, mutect2, varscan2
- GUCY1A1 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as COSV56655411; called by muse, mutect2, varscan2
- HCN4 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV56081225, COSV56086676; called by muse, mutect2, varscan2
- HECW1 | c.760A>T p.K254* | Nonsense Mutation (SNP) | VAF 12/214 reads (6%) | catalogued as COSV101223084, COSV67822202; called by muse, mutect2
- HRNR | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs773313985, COSV64261943; called by muse, mutect2, varscan2
- HTR2C | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 194/227 reads (85%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1556468184, COSV52210673; called by muse, mutect2, varscan2
- HYDIN | c.7963G>C p.E2655Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV59267404; called by muse, mutect2, varscan2
- IFI16 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV55537652, COSV99857240; called by muse, mutect2
- IGHV1OR21-1 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 101/355 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772437101; called by muse, mutect2
- IGKV1D-8 | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 105/421 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs552867096; called by muse, mutect2, varscan2
- IGSF1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV63837108; called by muse, mutect2, varscan2
- INSRR | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1367479652, COSV63876618; called by muse, mutect2, varscan2
- JAML | c.911G>T p.S304I (on ENST00000356289 / NM_001098526.2; = p.S294I on NM_153206.3) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52629195; called by muse, mutect2, varscan2
- KAT14 | c.2095G>C p.A699P | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66608993; called by muse, mutect2, varscan2
- KCTD8 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs769382363, COSV63585801; called by muse, mutect2, varscan2
- KLHL20 | c.978G>C p.W326C | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV52944488; called by muse, mutect2, varscan2
- KMT5B | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 69/85 reads (81%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV58569184; called by muse, mutect2, varscan2
- LARGE2 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99138220; called by muse, mutect2
- LHFPL6 | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 28/785 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV101095110; called by muse, mutect2
- LIFR | c.1148A>G p.K383R | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV54697831; called by muse, mutect2, varscan2
- LMBRD2 | c.1471A>C p.N491H | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56952173; called by muse, mutect2, varscan2
- LRRTM3 | c.1063G>T p.V355L | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1441518688, COSV63670703; called by muse, mutect2, varscan2
- MAGI2 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV62642519; called by muse, mutect2, varscan2
- MASP1 | c.820A>T p.S274C | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV51463143; called by muse, mutect2, varscan2
- MCC | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs371091745, COSV56728304; called by muse, mutect2, varscan2
- MCF2 | c.1164T>G p.F388L | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV100644615; called by muse, mutect2
- MTOR | c.6999T>G p.I2333M | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63877031; called by muse, mutect2, varscan2
- MYH14 | c.4370G>A p.R1457Q | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs776280390, COSV51823754; called by muse, mutect2, varscan2
- MYO1H | c.2030T>C p.I677T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100183293; called by muse, mutect2, varscan2
- NALCN | c.2457-1G>C p.X819_splice | Splice Site (SNP) | VAF 24/372 reads (6%) | catalogued as COSV99213795; called by muse, mutect2
- NGFR | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.25); PolyPhen benign (0.139); catalogued as rs534528579, COSV50803870; called by muse, mutect2, varscan2
- NRXN2 | c.2601G>C p.E867D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV55461439; called by muse, mutect2, varscan2
- NUP188 | c.971T>C p.L324S | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101001263; called by muse, mutect2
- OGDHL | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs772306801, COSV65101628; called by muse, mutect2, varscan2
- OR10H2 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1430564530, COSV59946792; called by muse, mutect2, varscan2
- OR4C11 | c.204T>G p.D68E | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV56354138, COSV56354737; called by muse, mutect2
- OR4K5 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 260/1355 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV60004933; called by muse, mutect2, varscan2
- OR52E4 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 321/402 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1324170420, COSV57625872; called by muse, mutect2
- OR52N1 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 101/136 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57693950, COSV57693989; called by muse, mutect2, varscan2
- OR5K2 | c.137T>A p.V46E | Missense Mutation (SNP) | VAF 18/608 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101415958; called by muse, mutect2
- OR5M1 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101591559, COSV73202120; called by muse, mutect2
- OR5M3 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392520, COSV56565606; called by muse, mutect2, varscan2
- OR6F1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.359); catalogued as COSV57469163; called by muse, mutect2
- PCDHA2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV65370441; called by muse, mutect2, varscan2
- PCDHAC2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53846314; called by muse, mutect2, varscan2
- PCDHB14 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV53390695; called by muse, mutect2, varscan2
- PCDHB8 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 88/672 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV99176432; called by muse, mutect2, varscan2
- PCDHGA2 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 106/208 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.049); catalogued as COSV54013462; called by muse, mutect2, varscan2
- PCF11 | c.3715C>A p.P1239T | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223940576, COSV53536824; called by muse, mutect2, varscan2
- PDGFRA | c.845T>A p.V282E | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV57265908, COSV57272418; called by muse, mutect2, varscan2
- PHC2 | c.2158G>A p.V720M (on ENST00000257118 / NM_198040.2; = p.V185M on NM_004427.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57107388; called by muse, mutect2
- PICALM | c.184A>T p.S62C | Missense Mutation (SNP) | VAF 5/145 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100707757; called by muse, mutect2
- PKD1L1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs771010161, COSV56975439; called by muse, mutect2, varscan2
- PLCG2 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs778265649, COSV63867552, COSV63879236; ClinVar: uncertain significance; called by muse, mutect2
- PRAMEF15 | c.1232G>C p.C411S | Missense Mutation (SNP) | VAF 257/758 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1173534893; called by muse, mutect2, varscan2
- PRMT8 | c.1079T>C p.M360T | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV54218083; called by muse, mutect2, varscan2
- PTPRM | c.2620G>A p.G874R | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV59877143, COSV99046028; called by muse, mutect2, varscan2
- ROCK1 | c.3915A>C p.Q1305H | Missense Mutation (SNP) | VAF 81/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67698791; called by muse, mutect2, varscan2
- RYR2 | c.12209C>T p.A4070V | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.218); catalogued as rs777939821, COSV63699840; called by muse, mutect2, varscan2
- SCN9A | c.5516T>G p.L1839R (on ENST00000303354; = p.L1828R on NM_002977.3) | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57621192; called by muse, mutect2, varscan2
- SLC25A18 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53656822, COSV53659640; called by muse, mutect2, varscan2
- SLC30A3 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs749270034, COSV51986908; called by muse, mutect2
- SLC44A5 | c.1973T>A p.F658Y | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV63772792; called by muse, mutect2, varscan2
- SMAD4 | c.1310T>A p.V437D | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61693216; called by muse, mutect2, varscan2
- SMR3A | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as rs1404759283, COSV99895571; called by muse, mutect2
- SOHLH2 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 53/482 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV58520560, COSV58522859; called by muse, mutect2, varscan2
- SPEF2 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 170/796 reads (21%) | catalogued as COSV56799877; called by muse, mutect2, varscan2
- SPIDR | c.728C>G p.A243G | Missense Mutation (SNP) | VAF 165/449 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs782244112, COSV52388120; called by muse, mutect2, varscan2
- SPOCD1 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as rs748892059, COSV57099216; called by muse, mutect2, varscan2
- SPOPL | c.84A>C p.K28N | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as COSV54515938; called by muse, mutect2, varscan2
- SPTBN2 | c.6601G>A p.E2201K | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.46); PolyPhen benign (0.107); catalogued as rs1256781556, COSV59459733; called by muse, mutect2, varscan2
- SRGAP3 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 140/622 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs768114904, COSV64531479; called by muse, mutect2, varscan2
- SRSF5 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 89/116 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as rs759069069, COSV53682259; called by muse, mutect2, varscan2
- STK31 | c.1524G>C p.E508D | Missense Mutation (SNP) | VAF 112/556 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV63458821; called by muse, mutect2, varscan2
- SYCP2L | c.922A>G p.R308G | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV51656820; called by muse, mutect2, varscan2
- SYNCRIP | c.184A>C p.I62L | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV62289097; called by muse, mutect2
- SYNE1 | c.16327A>G p.T5443A (on ENST00000367255 / NM_182961.4; = p.T5372A on NM_033071.3) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs754256537, COSV55075546; called by muse, mutect2, varscan2
- SYNE1 | c.524A>T p.K175M (on ENST00000367255 / NM_182961.4; = p.K182M on NM_033071.3) | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV55075560; called by muse, mutect2, varscan2
- TEX55 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 59/544 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV55212582; called by muse, mutect2
- TGFB2 | c.530T>G p.L177* | Nonsense Mutation (SNP) | VAF 108/661 reads (16%) | catalogued as COSV65110698; called by muse, mutect2, varscan2
- TMEM52B | c.508C>G p.P170A (on ENST00000381923 / NM_001079815.1; = p.P150A on NM_153022.4) | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as COSV53729431; called by muse, mutect2, varscan2
- TRPA1 | c.981_984del p.Y327* | Frame Shift Del (DEL) | VAF 38/109 reads (35%) | catalogued as rs1217915791; called by mutect2, pindel, varscan2
- TSHZ2 | c.2314A>G p.S772G | Missense Mutation (SNP) | VAF 161/488 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61590884; called by muse, mutect2, varscan2
- VCAN | c.1910G>C p.G637A | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV54114455; called by muse, mutect2, varscan2
- VPS33B | c.1298C>A p.T433N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs918085232, COSV60981433; called by muse, mutect2
- WDR92 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV54562685; called by muse, mutect2, varscan2
- XIRP1 | c.4393C>T p.Q1465* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV61140484; called by muse, mutect2, varscan2
- ZBED6CL | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs776445212, COSV59605298; called by muse, mutect2, varscan2
- ZFHX4 | c.10396C>T p.L3466F | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51489863, COSV99262619; called by muse, mutect2, varscan2
- ZFP2 | c.221A>G p.H74R | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63726793; called by muse, mutect2, varscan2
- ZFP36 | c.979C>G p.R327G (on ENST00000594442; = p.R321G on NM_003407.5) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99953714; called by muse, mutect2
- ZNF148 | c.543A>T p.R181S | Missense Mutation (SNP) | VAF 104/448 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62307078; called by muse, mutect2, varscan2
- ZNF354A | c.1371G>C p.E457D | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV59984573; called by muse, mutect2, varscan2
- ZNF638 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 355/571 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs751043105, COSV52494988; called by muse, mutect2, varscan2
- ZNF880 | c.1175A>C p.K392T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.055); catalogued as COSV69906779; called by muse, mutect2, varscan2
- APC | c.4063del p.S1355Lfs*60 | Frame Shift Del (DEL) | VAF 135/312 reads (43%) | called by mutect2, pindel, varscan2
- APC | c.4655_4656del p.E1552Gfs*6 | Frame Shift Del (DEL) | VAF 116/506 reads (23%) | called by pindel, varscan2
- FANCD2 | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.05); called by muse, mutect2
- ROBO2 | c.2686dup p.T896Nfs*23 | Frame Shift Ins (INS) | VAF 35/132 reads (27%) | called by mutect2, pindel, varscan2
- ADCY2 | c.2709C>T p.S903= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs774455530, COSV57862905; called by muse, mutect2, varscan2
- AGMO | c.180T>C p.I60= | Silent (SNP) | VAF 12/350 reads (3%) | catalogued as COSV100693865; called by muse, mutect2
- CHL1 | c.1995C>A p.V665= (on ENST00000397491 / NM_001253387.1; = p.V681= on NM_006614.4) | Silent (SNP) | VAF 108/345 reads (31%) | catalogued as COSV56603624; called by muse, mutect2, varscan2
- CHST15 | c.99G>A p.A33= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs760179080, COSV60563148; called by muse, mutect2, varscan2
- COL2A1 | c.3927C>T p.D1309= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as rs774100575, COSV61529753; ClinVar: likely benign; called by muse, mutect2, varscan2
- EDNRB | c.459G>A p.A153= (on ENST00000377211 / NM_001201397.1; = p.A63= on NM_000115.5) | Silent (SNP) | VAF 79/91 reads (87%) | catalogued as COSV57518710; called by muse, mutect2, varscan2
- ERBB4 | c.2148T>G p.T716= | Silent (SNP) | VAF 6/152 reads (4%) | catalogued as COSV53551284, COSV53560427; called by muse, mutect2
- FAM124A | c.909T>A p.T303= (on ENST00000322475 / NM_001242312.2; = p.T339= on NM_145019.4) | Silent (SNP) | VAF 186/292 reads (64%) | catalogued as COSV54479487; called by muse, mutect2, varscan2
- FLG2 | c.5385C>G p.T1795= | Silent (SNP) | VAF 45/810 reads (6%) | catalogued as rs758336615, COSV66167348; called by muse, mutect2
- FRY | c.7002T>A p.I2334= | Silent (SNP) | VAF 31/388 reads (8%) | catalogued as COSV100968944; called by muse, mutect2
- GJB2 | c.357G>A p.E119= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as COSV67010861; called by muse, mutect2, varscan2
- HTR2A | c.744C>G p.T248= | Silent (SNP) | VAF 28/445 reads (6%) | catalogued as COSV101096632; called by muse, mutect2
- HUNK | c.543G>T p.G181= | Silent (SNP) | VAF 16/333 reads (5%) | called by muse, mutect2
- IGKV1-12 | c.36C>T p.L12= | Silent (SNP) | VAF 346/1151 reads (30%) | catalogued as rs1233547187; called by muse, mutect2, varscan2
- IGSF1 | c.1803T>C p.P601= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV100811964; called by muse, mutect2, varscan2
- INF2 | c.564C>T p.S188= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as rs746732992, COSV53030958; ClinVar: likely benign; called by muse, mutect2, varscan2
- KANK4 | c.1026C>A p.I342= | Silent (SNP) | VAF 5/148 reads (3%) | catalogued as COSV100587210; called by muse, mutect2
- KLHL24 | c.1323G>A p.K441= | Silent (SNP) | VAF 318/702 reads (45%) | catalogued as COSV54428256; called by muse, mutect2, varscan2
- MTG2 | c.777G>A p.L259= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100895149; called by muse, mutect2, varscan2
- NLRP2 | c.1347G>A p.T449= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs375208908; called by muse, mutect2, varscan2
- NMUR2 | c.234G>A p.T78= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as COSV54918203; called by muse, mutect2, varscan2
- OR2A12 | c.300T>G p.T100= | Silent (SNP) | VAF 65/531 reads (12%) | catalogued as COSV68821877; called by muse, mutect2, varscan2
- PCDHB4 | c.2211C>T p.D737= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as rs782131892, COSV52025998; called by muse, mutect2, varscan2
- PGK2 | c.399A>G p.Q133= | Silent (SNP) | VAF 58/349 reads (17%) | catalogued as rs557577912, COSV100505472, COSV59165313; called by muse, mutect2, varscan2
- PKIB | c.18A>C p.S6= | Silent (SNP) | VAF 98/323 reads (30%) | catalogued as COSV57797180; called by muse, mutect2, varscan2
- PRKCQ | c.1986C>T p.S662= | Silent (SNP) | VAF 154/695 reads (22%) | catalogued as COSV54117489; called by muse, mutect2, varscan2
- PYROXD2 | c.999G>A p.V333= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as COSV65331210; called by muse, mutect2, varscan2
- RPL4 | c.792C>T p.Y264= | Silent (SNP) | VAF 62/185 reads (34%) | catalogued as rs752785467, COSV57182501; called by muse, mutect2, varscan2
- SDC1 | c.570G>A p.R190= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs755143681, COSV54341246; called by muse, mutect2, varscan2
- SLCO1C1 | c.2041A>C p.R681= | Silent (SNP) | VAF 8/212 reads (4%) | catalogued as COSV99858770; called by muse, mutect2
- SORCS1 | c.2487G>A p.Q829= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99544549; called by muse, mutect2, varscan2
- TBL1Y | c.540T>A p.S180= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV60733742; called by muse, mutect2, varscan2
- TLE3 | c.402C>T p.S134= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as COSV58173585; called by muse, mutect2, varscan2
- TMEM72 | c.465C>T p.S155= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as rs768619195, COSV67460255; called by muse, mutect2, varscan2
- TRIM68 | c.1038C>T p.I346= | Silent (SNP) | VAF 62/82 reads (76%) | catalogued as rs955140989, COSV56167699; called by muse, mutect2, varscan2
- TXNDC5 | c.291G>T p.P97= | Silent (SNP) | VAF 62/118 reads (53%) | catalogued as COSV65729878, COSV65730863; called by muse, mutect2, varscan2
- ZFHX4 | c.9270C>T p.H3090= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as rs1168818095, COSV50493499; called by muse, mutect2, varscan2
- ZNF474 | c.930T>G p.P310= | Silent (SNP) | VAF 12/235 reads (5%) | catalogued as COSV99682065; called by muse, mutect2
- ZNF644 | c.213G>A p.T71= | Silent (SNP) | VAF 82/158 reads (52%) | catalogued as COSV61349873; called by muse, mutect2, varscan2
- MIR181A1 | n.34G>A | RNA (SNP) | VAF 293/598 reads (49%) | catalogued as rs1406655910; called by muse, mutect2, varscan2
- SNORD116-29 | n.32T>G | RNA (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
